Surgical pathology report (de-identified scan), TCGA case TCGA-L4-A4E5, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Gundersen Lutheran Health System, specimen TCGA-L4-A4E5-01A (Primary Tumor).

[page 1 of 2]
Patient:

Med. Record. No.:

Date of Birth:

Submitted by:

Report also to:

Age:

Sex: F

Pathology #:

Date of Procedure:

Date Received:

Pathology Report

**** Supplemental Report Follows ** See Below ****

DIAGNOSIS:

SPECIMEN

Specimen type: Lobectomy

Tumor site: Left upper lobe

TUMOR

Histologic type: Adenocarcinoma

Histologic grade: Moderately differentiated (G2 of 4)

Tumor size: 2.7cm

Tumor focality: Unifocal

Direct extension of tumor: No invasion of visceral pleura or adjacent structures

Tumor-associated atelectasis/obstructive pneumonitis: Absent

Lymphovascular space invasion: Absent

Additional findings: None

MARGINS

All margins negative for carcinoma

Distance to nearest margin: 3cm

Nearest margin: Bronchial margin

LYMPH NODES

All sampled lymph nodes are benign

Number of nodes evaluated: 7

Comment:

Lymph nodes consist of 6 peribronchial lymph nodes within the lobectomy specimen, and one separately submitted left inferior pulmonary ligament lymph node biopsy (specimen B).

STAGING (AJCC)

Primary Tumor: pT1

Lymph Nodes: pN0

IHPAA Discrepancy		✓

CLINICAL INFORMATION:

Lung mass.

[page 2 of 2]
Patient: [REDACTED]

SPECIMEN(S) RECEIVED:

- A. Left upper lobe – check bronchial margins.
- B. Left inferior pulmonary ligament lymph node

GROSS DESCRIPTION:

A. Received fresh is a 191 gram, 18 x 11 x 5 cm lobe of lung with a glistening, mottled pink-gray to red-purple pleural surface with a large amount of black anthracotic pigment present. There is a firm, multinodular 3.3 x 2.8 x 2.7 cm tan-gray mass located approximately 3 cm away from the bronchial margin which grossly extends to and forms a scar-like lesion of the pleural surface. There are numerous soft gray-black lymph nodes present at the hilum, 0.4 to 0.9 cm. Sectioning through the rest of the lobe reveals a soft, spongy red-gray to gray-black cut surface. A portion of normal lung and a portion of tumor is collected for the The
bronchial margin is submitted for frozen section; frozen remnant submitted in A1. A2-A4 – mass; A5 – lung; A6-A7 – intact hilar lymph nodes; A8 – hilar node, bisected.

FROZEN SECTION DIAGNOSIS: Bronchial margin negative for malignancy. Reported to intraoperatively at [REDACTED]

- B. Received in formalin is a soft 10 x 7 x 3 mm gray-black lymph node. Bisected and submitted in B1.

Slides were microscopically examined by the pathologist

Evaluation performed by [REDACTED]

**** SUPPLEMENTAL REPORT ****

An elastic (VVG) stain was utilized to assess the visceral pleura – no pleural invasion was identified. The case was also seen in retrospective review by [REDACTED], who agrees with the diagnosis. The diagnosis remains as originally reported above.

Supplemental Information reported by [REDACTED]

Source: NCI Genomic Data Commons file 1257d4c0-4a95-42d8-a321-6032f5a83c63 (TCGA-L4-A4E5.22CFA28A-0CE4-4806-97B0-32635D6DCE3F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).